Somatic mutation profile of tumor specimen 0DFKGQ from CCDI case PBBPTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.5 years (3,457 days).
Specimen 0DFKGQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9489dace-8570-426a-8e10-d8bd179fb969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFKGR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/400fef5d-0ccc-424c-b348-e31180bb2869

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Translation Start Site 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 306/390 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs45517258, CM023179, CM981950, COSV54765887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NAV1 | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 18/612 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs969257345; called by muse, mutect2
- ZPR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 28/409 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs549846354; called by muse, mutect2
- ITPR1 | c.6032G>A p.C2011Y (on ENST00000354582; = p.C1956Y on NM_002222.7) | Missense Mutation (SNP) | VAF 78/1156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 62/731 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SSBP4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- KRT13 | c.1056G>A p.T352= | Silent (SNP) | VAF 76/734 reads (10%) | catalogued as rs762358997; called by muse, mutect2, varscan2
